Somatic mutation profile of tumor specimen C3L-07580-54 (aliquot CPT0450560002) from CPTAC case C3L-07580, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 81.3 years (29,689 days).
Specimen C3L-07580-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b953d406-b288-41d7-84ce-ddf645c5ea2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07580-50 (Buccal Cell Normal), aliquot CPT0450530002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de234503-fc72-48fe-9730-4c112274884e

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNC2 | c.2486G>T p.S829I | Missense Mutation (SNP) | VAF 64/541 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs767790901; called by muse, mutect2, varscan2
- HOXA5 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 115/245 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1369095715; called by muse, mutect2, varscan2
- NAP1L5 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 13/166 reads (8%) | catalogued as rs749014233; called by muse, mutect2
- SLC22A11 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 48/334 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as rs756887929, COSV57254704; called by muse, mutect2, varscan2
- DNAJC6 | c.1345G>A p.V449M | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- JAK1 | c.1906_1908del p.F636del | In Frame Del (DEL) | VAF 46/162 reads (28%) | called by pindel, varscan2
- PABPC5 | c.815G>C p.G272A | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.308); called by muse, mutect2
- PLAC1 | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 59/390 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERPINB12 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BIRC6 | c.4665A>G p.T1555= | Silent (SNP) | VAF 66/159 reads (42%) | catalogued as rs1238199027; called by muse, mutect2, varscan2
- NR4A3 | c.423C>T p.S141= | Silent (SNP) | VAF 47/83 reads (57%) | called by muse, mutect2, varscan2
- TRDC | c.192T>C p.Y64= | Silent (SNP) | VAF 19/203 reads (9%) | called by muse, mutect2
- USP17L2 | c.729C>A p.P243= | Silent (SNP) | VAF 124/487 reads (25%) | catalogued as rs1458487098, COSV100414671; called by mutect2, varscan2
- ZNF136 | c.444C>T p.P148= | Silent (SNP) | VAF 84/733 reads (11%) | catalogued as rs763966323, COSV100677947; called by muse, mutect2, varscan2
